Surgical pathology report (de-identified scan), TCGA case TCGA-IQ-A61H, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-IQ-A61H-01A (Primary Tumor).

[page 1 of 12]
PATIENT:

AGE/SEX: /M

REG DR:

Received:
Copies to:

Collected:

SPECIMEN ID:

- A. TONGUE - DISTAL BRANCH RIGHT LINGUAL FS, B. TONGUE - DEEP RIGHT TONGUE FS,
- C. NERVE - PROXIMAL MARGIN LEFT LINGUAL NERVE, D. TONGUE - DEEP POSTERIOR TONGUE MARGIN,
- E. TONSIL - LEFT TONSIL, F. MUSCLE - DEEP LEFT FLOOR MOUTH MUSCLE,
- G. NERVE - MARGINAL MANDIBULAR NERVE, H. TONGUE - LEFT THREE QUARTER GLOUSECTOMY,
- I. SOFT TISSUE - TISSUE ON LT ANTERIOR MANDIBULE,
- J. SOFT TISSUE - TISSUE ON RT ANTERIOR MANDIBLE,
- K. RETROMOLAR AREA OF MOUTH - INFERIOR MARGIN LT RETOMOLAR,
- L. RETROMOLAR AREA OF MOUTH - DEEP LATERAL RETROMOLAR, M. MOUTH - DEEP POSTERIOR,
- N. TONGUE - POSTERIOR ORAL TONGUE, O. TONGUE - VENTRAL TONGUE CLIP ANTERIOR,
- P. MOUTH - RT FLOOR OF MOUTH, Q. TONGUE - TONGUE OF BASE,
- S. LYMPH NODE - ADDITIONAL LEVEL 1A,
- T. LYMPH NODE - LYMPH NODE AT SUPERIOR THYROID VESSEL,
- U. NECK, NOS - RT LEVEL 1B NECK DISSECTION,
- V. NECK, NOS - LEFT NECK DISSECTION LEVEL 3&4,
- W. NECK, NOS - LEFT NECK DISSECTION LEVEL 2B,
- X. NECK, NOS - RT MODIFIED RADICAL NECK DISSECTION

A. DISTAL BRANCH RIGHT LINGUAL NERVE:

No malignancy seen.

B. DEEP RIGHT TONGUE:

No malignancy seen.

C. PROXIMAL MARGIN LEFT LINGUAL NERVE:

ICD-O-3
Carcinoma, squamous cell
keratinizing NOS 8071/3
Site Tongue NOS C02.9
2015/14/13

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call [REDACTED] and
return the report to us by mail.

[page 2 of 12]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

No malignancy seen.

D. DEEP POSTERIOR TONGUE MARGIN:

No malignancy seen.

E. LEFT TONSIL:

No malignancy seen.

F. DEEP LEFT FLOOR OF MOUTH MUSCLE:

No malignancy seen.

G. MARGINAL MANDIBULAR NERVE:

No malignancy seen.

H. LEFT THREE QUARTER GLOSSECTOMY:

Invasive moderately differentiated keratinizing squamous cell carcinoma, 3.5 cm in greatest dimension.

Surgical margins: Uninvolved.

Although this neoplasm is present in close proximity to peripheral nerve in several foci, no definitive perineural invasion seen.

No lymphovascular invasion seen.

Seven lymph nodes, no carcinoma seen (0/7).

AJCC, T2 NO M N/A

See tumor summary.

I. TISSUE ON LEFT ANTERIOR MANDIBULAR:

No malignancy seen.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 3 of 12]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

J. TISSUE ON RIGHT ANTERIOR MANDIBULAR:

No malignancy seen.

K. INFERIOR MARGIN LEFT RETROMOLAR:

No malignancy seen.

L. DEEP LATERAL RETROMOLAR:

No malignancy seen.

M. DEEP POSTERIOR:

No malignancy seen.

N. POSTERIOR ORAL TONGUE:

No malignancy seen.

O. VENTRAL TONGUE CLIP ANTERIOR:

No malignancy seen.

P. RIGHT FLOOR OF MOUTH:

No malignancy seen.

Q. TONGUE OF BASE:

No malignancy seen.

R. INFERIOR MARGIN LEFT RETROMOLAR AREA:

No malignancy seen.

S. ADDITIONAL LEVEL 1A:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 4 of 12]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

No malignancy seen.

T. LYMPH NODE AT SUPERIOR THYROID VESSEL:

Fibroadipose tissue.

No lymph nodes identified.

Specimen submitted entirely for histologic evaluation.

U. RIGHT LEVEL 1B NECK DISSECTION:

Five lymph nodes, no carcinoma seen (0/5).

Salivary gland parenchyma with no specific histological changes.

V. LEFT NECK DISSECTION LEVEL 3&4:

Twenty two lymph nodes, no carcinoma seen (0/22).

W. LEFT NECK DISSECTION LEVEL 2B:

Five lymph nodes, no carcinoma seen (0/5).

X. RIGHT MODIFIED RADICAL NECK DISSECTION:

Thirteen lymph nodes, no carcinoma seen (0/13).

Lip and Oral Cavity Tumor Summary:

Specimen:

- Ventral surface of tongue, not otherwise specified (NOS)

Received:

- In formalin

Procedure:

- Resection

- Glossectomy

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 5 of 12]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Specimen Integrity:

- Intact

Specimen size:

- Greatest dimension: 6.5 x 6.0 x 3.0 cm

Specimen Laterality:

- Left

Tumor Site:

- Ventral surface of tongue, NOS

Tumor Focality:

- Single focus

Tumor Size:

- Greatest dimension: 3.5 cm
- Additional dimensions: 2.0 x 1.5 cm

Histologic Type:

- Squamous cell carcinoma, conventional

Histologic Grade:

- G2: Moderately differentiated

Margins:

- Margins uninvolved by invasive carcinoma

Lymph-Vascular Invasion:

- Not identified

Perineural Invasion:

- Not identified

Lymph Nodes, Extranodal Extension:

- Not identified

Pathologic Staging (pTNM)

- Primary Tumor (pT): pT2:
- Tumor more than 2 cm but not more than 4 cm in greatest dimension.
- Regional Lymph Nodes (pN): pN0
- No regional lymph node metastasis
- Number examined: 53
- Number involved: 0
- Distant Metastasis (pM):
- Not applicable

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 6 of 12]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 7 of 12]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 8 of 12]
(Continued)

GROSS DESCRIPTION:

- A. Received fresh labeled "Distal branch, right lingual nerve" are tiny soft tissue fragments measuring 0.2 x 0.1 x 0.1 cm. Submitted in toto in 1 cassette for frozen section.
- B. Received fresh labeled "Deep right tongue" are 2 reddish soft tissue fragments measuring in aggregate 2.0 x 0.5 x 0.2 cm. Submitted in toto in 1 cassette for frozen section.
- C. Received fresh labeled "Proximal margin, left lingual nerve" is grey-tan soft tissue fragment measuring 0.3 x 0.2 x 0.1 cm. Submitted in toto in 1 cassette for frozen section.
- D. Received fresh labeled "Deep posterior tongue margin" is a grey-tan soft tissue fragment measuring 0.7 x 0.5 x 0.2 cm. Submitted in toto in 1 cassette for frozen section.
- E. Received fresh labeled "Left tonsil" is a grey-tan soft tissue fragment measuring 1.0 x 1.0 x 0.2 cm. Submitted in toto in 1 cassette bisected for frozen section.
- F. Received fresh labeled "Deep left floor of mouth muscle" is a red-tan soft tissue fragment measuring 2.0 x 1.0 x 0.2 cm. Submitted in toto in 1 cassette for frozen section.
- G. Received fresh labeled "Margin at mandibular nerve" is a grey-tan soft tissue fragment measuring 1.0 x 1.0 x 0.1 cm. Submitted in toto in 1 cassette for frozen section.
- H. Received fresh labeled "Glossectomy left three quarter, black suture, tip of tongue white suture medial" is a reddish irregular-shaped fragment of tongue measuring 8.0 x 3.0 x 1.5 cm. Attached to deep/posterior aspect there is yellow fibroadipose tissue measuring in aggregate 6.5 x 6.0 x 3.0 cm. Specimen is inked as follows: anterior aspect inked yellow, medial aspect inked orange, posterior aspect inked black and inferior aspect inked in green. In the ventral aspect of the tongue, there is grey-white ill-defined lesion measuring 3.5 x 2.0 x 1.5 cm located towards medial aspect at 1.0 cm from each. It is 2.0 cm from anterior aspect, 1.7 cm from lateral, 3.0 cm from posterior, 1.0 cm from inferior aspect. Representative section to research (tissue bank). Cut sections reveal grey-white and ill-defined tumor aspect. The salivary gland is present and grossly unremarkable as well as the reddish skeletal muscle. There are 7 lymph nodes measuring 0.8 cm in greatest dimension. Representative sections are submitted in 17 cassettes as follows:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 9 of 12]
(Continued)

GROSS DESCRIPTION: (Continued)

Cassette #1: Perpendicular anterior aspect
Cassette #2: Perpendicular posterior aspect
Cassette #3: Perpendicular medial aspect
Cassettes #4,5: Perpendicular lateral aspect
Cassette #6: Tumor in relation with deep aspect
Cassettes #7-9: Representative sections of tumor
Cassettes #10: Representative sections of salivary gland.
Cassettes #11-17: One lymph node bisected.

- I. Received fresh labeled "Tissue on left anterior mandible" is a yellow-tan soft tissue fragment measuring 0.5 x 0.5 x 0.1 cm. Submitted in toto in 1 cassette for frozen section.
- J. Received fresh labeled "Tissue right anterior mandible" is a grey-tan soft tissue fragment measuring 0.5 x 0.5 x 0.2 cm. Submitted in toto in 1 cassette for frozen section.
- K. Received fresh labeled "Inferior margin left retromolar area" are 2 reddish soft tissue fragments measuring 2.5 x 0.5 x 0.2 cm. Submitted in toto in 1 cassette for frozen section.
- L. Received fresh labeled "Deep lateral retromolar region" is a red-tan soft tissue fragment measuring 1.0 x 0.7 x 0.2 cm. Submitted in toto in 1 cassette for frozen section.
- M. Received fresh labeled "Deep posterior margin" is a pale tan soft tissue fragment measuring 1.5 x 0.5 x 0.4 cm. Submitted in toto in 1 cassette for frozen section.
- N. Received fresh labeled "Posterior oral tongue-clip anterior" is a pale tan soft tissue fragment measuring 3.0 x 0.6 x 0.2 cm. The resection margin is inked in orange. Submitted in toto in 1 cassette for frozen section.
- O. Received fresh labeled "Ventral tongue clip anterior" is a red-tan soft tissue fragment measuring 3.0 x 0.5 x 0.2 cm. The clip is inked orange. Submitted in toto in 1 cassette for frozen section.
- P. Received fresh labeled "Right floor of mouth" is a grey-tan soft tissue fragment measuring 1.0 x 1.0 x 0.3 cm. Submitted in toto in 1 cassette for frozen section.
- Q. Received fresh labeled "Tongue of base" is a grey tan soft tissue fragment measuring 2.5 x 0.5 x 0.2 cm. The deep area inked orange. Submitted in toto in 1 cassette for

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 10 of 12]
(Continued)

GROSS DESCRIPTION: (Continued)
frozen section.

- R. Received fresh labeled "Inferior margin, left retromolar area" is a red-tan soft tissue fragment measuring 2.0 x 0.5 x 0.2 cm. There is a clip, inked in orange. Specimen is submitted in toto in 1 cassette.
- S. Received fresh labeled "Additional level 1A" is a grey-tan soft tissue fragment measuring 1.5 x 0.5 x 0.5 cm. Submitted in toto in 1 cassette.
- T. Received in formalin labeled "Lymph node superior at thyroid vessel" is a yellow fibroadipose tissue measuring 3.0 x 2.0 x 1.0 cm. No lymph node is identified grossly. Submitted in toto in 3 cassettes.
- U. Received in formalin labeled "Right level 1B neck dissection" is a yellow fibroadipose tissue measuring 5.0 x 3.0 x 1.0 cm. The salivary gland is present measuring 4.0 x 4.0 x 1.0 cm which is grossly unremarkable. Also, there are 3 possible lymph nodes. Representative sections in 7 cassettes as follows:
- Cassette #1: Salivary gland
Cassettes #2,3: One lymph node bisected
Cassette #4: One lymph node in toto
Cassettes #5-7: Adipose tissue
- V. Received in formalin labeled "Left neck dissection level 3 and 4" is yellow fibroadipose tissue measuring 6.0 x 4.0 x 1.0 cm. There are 22 possible lymph nodes measuring up to 2.0 cm in greatest dimension. All of the lymph nodes are submitted in 10 cassettes as follows:
- Cassettes #1-4: One lymph node bisected
Cassettes #5-10: Three lymph nodes per cassette
- W. Received in formalin labeled "Left neck dissection level 2B" is yellow fibroadipose tissue measuring 2.0 x 1.5 x 0.5 cm. There is 1 lymph node measuring 0.4 cm in length. Submitted in toto in 4 cassettes multisected.
- X. Received in formalin labeled "Right modified radical neck dissection stitch superior" is yellow fibroadipose tissue measuring 2.0 x 1.0 cm. There are 12 possible lymph nodes measuring up to 1.0 cm in greatest dimension. All of the lymph nodes are submitted in 8 cassettes as follows:
- Cassettes #1,2: Lymph nodes towards the stitch

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 11 of 12]
(Continued)

GROSS DESCRIPTION: (Continued)

Cassette #1: Bisected

Cassette #2: One lymph node per cassette

Cassettes #3-6: One lymph node per cassette

Cassettes #7,8: Three lymph nodes per cassette

OPERATING ROOM CONSULT (FS-CYT)

- A. DISTAL BRANCH RIGHT LINGUAL NERVE, FS: Small segment of nerve and muscle. No tumor present.
- B. DEEP RIGHT TONGUE, FS: Salivary gland parenchyma and muscle; no tumor present.
- C. PROXIMAL MARGIN LEFT LINGUAL NERVE, FS: Peripheral nerve; no tumor present.
- D. DEEP POSTERIOR TONGUE MARGIN, FS: Skeletal muscle; no tumor present.
- E. LEFT TONSIL, FS: Tonsillar tissue; no tumor present.
- F. DEEP LEFT FLOOR OF MOUTH MUSCLE, FS: Skeletal muscle; no tumor present.
- G. LYMPH NODE AT MARGIN OF MANDIBULAR NERVE, FS: Negative lymph node.
- I. TISSUE ON LEFT ANTERIOR MANDIBLE, FS: No tumor present.
- J. TISSUE ON RIGHT ANTERIOR MANDIBLE, FS: No tumor present.
- K. INFERIOR MARGIN LEFT RETROMOLAR, FS: Negative for carcinoma.
- L. DEEP LATERAL RETROMOLAR, FS: Negative for carcinoma.
- M. DEEP POSTERIOR, FS: Negative for carcinoma.
- N. POSTERIOR ORAL TONGUE, CLIP, FS: Negative for carcinoma.
- O. VENTRAL TONGUE, CLIP ANTERIOR, FS: Negative for carcinoma.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 12 of 12]
(Continued)

OPERATING ROOM CONSULT(FS-CYT): (Continued)

P. RIGHT FLOOR OF MOUTH, FS: Negative for carcinoma.

Q. TONGUE OF BASE, CLIP BASE, FS: Negative for carcinoma.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

Criteria	4/9/13	Yes	No
HPV Discrepancy			/

Source: NCI Genomic Data Commons file 4c222d38-fd33-490c-8fb3-c3679457947f (TCGA-IQ-A61H.85E48B95-E2D4-409A-B951-8045671073B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).